CCDI case PBCBIS — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e4cf8c71-dc5a-43a3-a9aa-28df6b587543

Demographics
Sex at birth: female; Race: asian.

Diagnoses (1)
1. Ependymoma, NOS: ICD-O-3 morphology code: 9391/3; Tissue or organ of origin: Cerebellum, NOS; Age at diagnosis: 12.5 years (4,576 days).

Biospecimens (3 samples)
- Sample 0DNCAF: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DNCH3: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DNCOM: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
